MMRF case MMRF_1054 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/00e9cfa7-d2e1-46b8-b0ff-d7f1da925097

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.3 years (21,310 days); ISS stage: II; Days to last known disease status: 1,828 days (5.0 years); Days to last follow up: 1,828 days (5.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 21 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 112 days.
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 29 days; Days to treatment end: 112 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 112 days; Days to treatment end: 568 days (1.6 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 112 days; Days to treatment end: 162 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 112 days; Days to treatment end: 169 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 167 days.
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 169 days; Days to treatment end: 568 days (1.6 years).
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 568 days (1.6 years); Days to treatment end: 680 days (1.9 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -8 (ECOG 0): M Protein 6.53 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.742 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 108 mg/dL; Immunoglobulin G 88.2 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 3.06 µg/mL; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.28 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 34 g/L; Total Protein 13.8 g/dL; Glucose 5.34 mmol/L; C-Reactive Protein 0.1 mg/dL.
- Day 50 (ECOG 0): M Protein 2.86 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 31.9 mg/dL; Immunoglobulin G 33.5 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 1.78 µg/mL; Lactate Dehydrogenase 4.92 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 280 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 9 g/dL; Glucose 2.81 mmol/L.
- Day 197 (ECOG 0): Hemoglobin 7.19 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 326 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.1 mmol/L; Albumin 35 g/L; Total Protein 7.1 g/dL; Glucose 2.92 mmol/L.
- Day 281 (ECOG 0): M Protein 0.95 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.68 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 1.23 µg/mL; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 4.24 mmol/L.
- Day 358: M Protein 0.54 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Lactate Dehydrogenase 3.67 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 5.01 mmol/L.
- Day 423 (ECOG 0): M Protein 0.38 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.983 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.65 mg/dL; Immunoglobulin G 7.91 g/L; Immunoglobulin A 0.87 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.1 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 4.57 mmol/L.
- Day 568 (ECOG 0): M Protein 0.42 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.92 mg/dL; Immunoglobulin G 7.4 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 3.97 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 306 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 6.4 g/dL; Glucose 4.46 mmol/L.
- Day 666 (ECOG 0): M Protein 0.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.45 mg/dL; Immunoglobulin G 7.61 g/L; Immunoglobulin A 0.95 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.1 mmol/L; Albumin 36 g/L; Total Protein 6.4 g/dL; Glucose 6.55 mmol/L.
- Day 757 (ECOG 0): M Protein 0.46 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.38 mg/dL; Immunoglobulin G 9.37 g/L; Immunoglobulin A 1.58 g/L; Immunoglobulin M 0.56 g/L; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 6 g/dL; Glucose 3.85 mmol/L.
- Day 848 (ECOG 0): M Protein 0.49 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.48 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 2.14 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 5.07 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 323 ×10⁹/L; Creatinine 41.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 33 g/L; Total Protein 6.6 g/dL; Glucose 4.62 mmol/L.
- Day 932 (ECOG 0): M Protein 0.54 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.64 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 1.96 g/L; Immunoglobulin M 0.32 g/L; Hemoglobin 8 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 291 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.38 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 5.01 mmol/L.
- Day 981: M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.8 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 1.89 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 47.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 4.18 mmol/L.
- Day 1,085 (ECOG 0): M Protein 0.47 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.95 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 1.83 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 7.94 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 48.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 4.07 mmol/L.
- Day 1,149: M Protein 0.51 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.24 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 10.8 g/L; Immunoglobulin M 0.34 g/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 46.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.08 mmol/L; Albumin 35 g/L; Total Protein 6.3 g/dL; Glucose 4.13 mmol/L.
- Day 1,233 (ECOG 0): M Protein 0.55 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.79 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 1.83 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 8.06 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 45.1 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 5.01 mmol/L.
- Day 1,345 (ECOG 1): M Protein 0.57 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.64 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 2.45 g/L; Immunoglobulin M 0.43 g/L; Lactate Dehydrogenase 6.38 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 40.7 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 6.2 g/dL; Glucose 4.51 mmol/L.
- Day 1,457 (ECOG 1): M Protein 0.43 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.11 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 2.03 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 46.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 4.35 mmol/L.
- Day 1,513: M Protein 0.51 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.56 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 2.62 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 45.1 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 4.24 mmol/L.
- Day 1,618: M Protein 0.45 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.5 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 2.6 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 46 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 5.45 mmol/L.
- Day 1,715: M Protein 0.47 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.11 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 2.38 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 45.1 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 4.73 mmol/L.
- Day 1,828: M Protein 0.61 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.66 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 2.47 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 3.58 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 46 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.23 mmol/L; Albumin 33 g/L; Total Protein 6.5 g/dL; Glucose 5.56 mmol/L.

Other clinical attributes
- Day -8: Weight: 58 kg; Height: 152 cm.

Family history
- Relative with cancer history: yes; Relationship type: Child.

Biospecimens (2 samples)
- Sample MMRF_1054_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -8 days.
- Sample MMRF_1054_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -8 days.
